Somatic mutation profile of tumor specimen HTMCP-03-06-02407-01A (aliquot HTMCP-03-06-02407-01A-01D-10409) from CGCI case HTMCP-03-06-02407, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 50.4 years (18,419 days).
Specimen HTMCP-03-06-02407-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8adfce9-10df-4802-87db-91071ff3ebd1.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02407-10A (Blood Derived Normal), aliquot HTMCP-03-06-02407-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31dc73cf-4366-437c-8ab9-16fecaf8c418

The open-access MAF lists 68 somatic variants for this specimen: 41 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 23, Nonsense Mutation 3, RNA 2, 5'UTR 1, Splice Region 1, Intron 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>A p.R505S (on ENST00000281708 / NM_001349798.2; = p.R425S on NM_018315.5) | Missense Mutation (SNP) | VAF 22/234 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2
- ABCB7 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); catalogued as COSV53723803; called by muse, mutect2
- ARID3B | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1223738272; called by muse, mutect2
- CDH6 | c.1805C>A p.A602E | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as COSV54066963, COSV54072851; called by muse, mutect2, varscan2
- CEP295 | c.4795C>T p.Q1599* | Nonsense Mutation (SNP) | VAF 30/396 reads (8%) | catalogued as COSV57356404; called by muse, mutect2
- DMXL2 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV51842051; called by muse, mutect2
- DOCK1 | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273560968, COSV99726669; called by muse, mutect2
- GOLGB1 | c.5752G>T p.E1918* | Nonsense Mutation (SNP) | VAF 26/322 reads (8%) | catalogued as COSV61472130; called by muse, mutect2
- GRM7 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 7/77 reads (9%) | catalogued as rs1225077372; called by muse, mutect2
- MCF2L | c.1498G>A p.E500K (on ENST00000375608; = p.E468K on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV65049882; called by muse, mutect2, varscan2
- MYO7B | c.3820G>A p.E1274K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.033); catalogued as rs997309454; called by muse, varscan2
- OGT | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV101035543; called by muse, mutect2, varscan2
- PCDHA6 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554132224, COSV65343232, COSV65346688; called by muse, mutect2, varscan2
- RALBP1 | c.1518G>C p.Q506H | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.44); catalogued as COSV50037430; called by muse, mutect2, varscan2
- RYR3 | c.6803C>T p.T2268M (on ENST00000389232; = p.T2269M on NM_001036.6) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.127); catalogued as rs201082522; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRRM4 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.445); catalogued as rs559217766, COSV57412500; called by muse, mutect2, varscan2
- TIGD7 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.247); catalogued as rs1020687224; called by muse, mutect2
- USP29 | c.228del p.N78Tfs*18 | Frame Shift Del (DEL) | VAF 31/296 reads (10%) | catalogued as COSV54239725; called by mutect2, pindel, varscan2
- USP34 | c.5749G>A p.E1917K | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.72); catalogued as COSV101276532; called by muse, mutect2, varscan2
- ZNF43 | c.429C>A p.S143R | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV61686474; called by muse, mutect2
- ZNF98 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV63334917; called by muse, mutect2, varscan2
- ZSWIM8 | c.1904G>A p.S635N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.278); catalogued as COSV67133972; called by muse, mutect2
- ANKRD30A | c.1108G>C p.E370Q (on ENST00000611781; = p.E314Q on NM_052997.2) | Missense Mutation (SNP) | VAF 17/287 reads (6%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.932); called by muse, mutect2
- APLP2 | c.279+3A>C | Splice Region (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- ARHGAP5 | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- CSMD3 | c.1415C>T p.S472F (on ENST00000297405 / NM_001363185.1; = p.S368F on NM_052900.3) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- DHX9 | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DMXL2 | c.1717G>T p.D573Y | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- EML3 | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1109 | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- LONRF3 | c.1474G>A p.E492K (on ENST00000371628 / NM_001031855.3; = p.E451K on NM_024778.5) | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MUC22 | c.3986C>G p.S1329C | Missense Mutation (SNP) | VAF 52/481 reads (11%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- MYO1D | c.1057dup p.C353Lfs*9 | Frame Shift Ins (INS) | VAF 10/99 reads (10%) | called by mutect2, pindel, varscan2
- MYO1E | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- NCOA1 | c.1048C>G p.Q350E | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PRDM15 | c.2486A>T p.H829L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SETX | c.3383C>G p.S1128C | Missense Mutation (SNP) | VAF 21/227 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2
- SSH2 | c.3461C>T p.S1154F | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.054); called by muse, mutect2
- TRPM7 | c.2354T>C p.I785T | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- UTP20 | c.5104G>A p.E1702K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- ZGRF1 | c.5360G>A p.G1787E | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS5 | c.921C>T p.I307= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs1437617339; called by muse, mutect2, varscan2
- ARMC4 | c.1470C>T p.I490= | Silent (SNP) | VAF 24/182 reads (13%) | catalogued as rs776786720, COSV59459391; called by muse, mutect2, varscan2
- ATE1 | c.933C>T p.T311= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as rs905500969, COSV56438404, COSV99816748, COSV99817287; called by muse, mutect2
- ATP10B | c.3879C>T p.L1293= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as rs978633219; called by muse, mutect2, varscan2
- CNTNAP4 | c.771C>T p.T257= | Silent (SNP) | VAF 18/194 reads (9%) | called by muse, mutect2
- CRYBG3 | c.6489G>C p.L2163= | Silent (SNP) | VAF 21/294 reads (7%) | called by muse, mutect2
- LRP1 | c.3726C>T p.F1242= | Silent (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- MAGEB1 | c.312C>T p.V104= | Silent (SNP) | VAF 11/137 reads (8%) | called by muse, mutect2
- MAP6 | c.2337G>T p.L779= | Silent (SNP) | VAF 14/87 reads (16%) | called by mutect2, varscan2
- MAP6 | c.1710G>A p.V570= | Silent (SNP) | VAF 22/256 reads (9%) | called by muse, mutect2
- MUC22 | c.3006C>T p.S1002= | Silent (SNP) | VAF 52/534 reads (10%) | catalogued as rs941275492, COSV73736495; called by muse, mutect2, varscan2
- NPAS2 | c.1899G>A p.P633= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs780286248, COSV59558865; called by mutect2, varscan2
- NTNG1 | c.165G>A p.T55= | Silent (SNP) | VAF 24/226 reads (11%) | catalogued as rs201567511, COSV99640065; called by muse, mutect2
- NTRK3 | c.1680C>T p.L560= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV100712237, COSV62315920; called by muse, mutect2, varscan2
- OTC | c.15G>A p.L5= | Silent (SNP) | VAF 21/199 reads (11%) | catalogued as rs755245595; called by muse, mutect2, varscan2
- PCDH17 | c.2313G>A p.Q771= | Silent (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- PDPR | c.96C>T p.A32= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as rs752258859; called by muse, mutect2
- PDZD7 | c.447C>T p.A149= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs374893110, COSV100931614; called by muse, varscan2
- RBM10 | c.2193C>G p.A731= | Silent (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- RPGR | c.1728C>T p.I576= | Silent (SNP) | VAF 23/305 reads (8%) | catalogued as rs145682975; called by muse, mutect2
- SOX5 | c.141C>T p.L47= | Silent (SNP) | VAF 13/190 reads (7%) | catalogued as COSV58630553, COSV58642406; called by muse, mutect2
- SUV39H1 | c.147C>T p.C49= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs782155743; called by muse, mutect2, varscan2
- URB1 | c.783G>A p.Q261= | Silent (SNP) | VAF 18/210 reads (9%) | catalogued as rs1246011026; called by muse, mutect2
- AC133485.7 | n.4547G>A | RNA (SNP) | VAF 7/117 reads (6%) | catalogued as rs1199458168; called by muse, mutect2
- CNOT1 | c.4434+171C>G | Intron (SNP) | VAF 14/80 reads (18%) | catalogued as COSV55321287; called by muse, mutect2, varscan2
- CYP4F34P | n.465C>T | RNA (SNP) | VAF 18/192 reads (9%) | called by muse, mutect2
- FBXO40 | c.-3G>A | 5'UTR (SNP) | VAF 12/66 reads (18%) | catalogued as rs372089012, COSV57528056; called by muse, mutect2, varscan2
